Surgical pathology report (de-identified scan), TCGA case TCGA-AP-A0LQ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site MSKCC, specimen TCGA-AP-A0LQ-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral fallopian tubes and ovaries (
- 2: SP: Abdominal Panniculectomy (
- 3: SP: Additional anterior cervical tissue
- 4: SP: Left external iliac lymph node
- 5: SP: Left obturator lymph node (
- 6: SP: Left hypogastric lymph node (
- 7: SP: Left common iliac lymph node (
- 8: SP: Left para-aortic lymph node (
- 9: SP: Right external iliac lymph node (
- 10: SP: Lateral right external iliac lymph node (
- 11: SP: Right obturator lymph node (
- 12: SP: Right common iliac lymph node
- 13: SP: Right para-aortic lymph node (

adenocarcinoma, endometrioid, NOS
8380/3
Site: Endometrium C54.1

hw
57.1"

DIAGNOSIS:

- 1) UTERUS, CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES; TOTAL HYSTERECTOMY WITH SALPINGO-OOPHORECTOMY:
- ADENOCARCINOMA OF ENDOMETRIUM, ENDOMETRIOID TYPE, NOS, FIGO GRADE II (6-50% SOLID GROWTH), NUCLEAR GRADE 2.
- THE TUMOR INVADES TO <= HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 1.0 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 19 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: LEIOMYOMAS.
- THE LEFT OVARY SHOWS ENDOMETRIOSIS.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.
- 2) SKIN AND SUBCUTANEOUS TISSUE, ABDOMEN; PANNICULECTOMY:
- UNREMARKABLE SKIN AND SUBCUTANEOUS ADIPOSE TISSUE.

** Continued on next page **

HIFAA Discrepancy		X

[page 2 of 2]
- 3) CERVIX, ANTERIOR, "ADDITIONAL TISSUE"; RESECTION:
- BENIGN FRAGMENT OF CERVICAL TISSUE.
- 4) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).
- 5) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- TWELVE BENIGN LYMPH NODES (0/12).
- 6) LYMPH NODES, LEFT HYPOGASTRIC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 7) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 8) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).
- 9) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 10) LYMPH NODES, LATERAL RIGHT EXTERNAL ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 11) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 12) LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).
- 13) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- FOUR BENIGN LYMPH NODES (0/4).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Source: NCI Genomic Data Commons file 7af753ca-0ea7-4359-8b85-33c40ae413b8 (TCGA-AP-A0LQ.D37DBE11-B7EA-4356-901C-35AF3A7FCC89.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).